Somatic mutation profile of tumor specimen ALCH-B3B3-TTP1-A (aliquot ALCH-B3B3-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3B3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.3 years (21,307 days).
Specimen ALCH-B3B3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7767ccb-344e-465d-94c2-b18a49ea8fbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3B3-NB1-A (Blood Derived Normal), aliquot ALCH-B3B3-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4798d9a1-778d-4c20-941a-9772835c9f89

The open-access MAF lists 44 somatic variants for this specimen: 32 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, RNA 3, Splice Region 1, Intron 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP19 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 62/648 reads (10%) | catalogued as rs750660230, COSV57395679; called by muse, mutect2
- ATXN2 | c.2774C>T p.S925F (on ENST00000550104; = p.S765F on NM_002973.4) | Missense Mutation (SNP) | VAF 96/484 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs1327389066; called by muse, mutect2, varscan2
- BEST3 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 153/2894 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766338045, COSV56993729, COSV56995604; called by muse, mutect2
- DPP6 | c.2509C>T p.R837W (on ENST00000377770 / NM_001364500.2; = p.R775W on NM_001936.5) | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs762178479, COSV59640722; called by muse, mutect2
- FAT4 | c.5243C>T p.T1748M | Missense Mutation (SNP) | VAF 46/714 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs202038981, COSV100629122; called by muse, mutect2
- FSTL4 | c.1340-5C>A | Splice Region (SNP) | VAF 62/616 reads (10%) | catalogued as rs750917171; called by muse, mutect2
- HECTD4 | c.12695C>T p.A4232V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV66400393; called by muse, mutect2
- IGSF9 | c.2920C>T p.P974S (on ENST00000368094 / NM_001135050.2; = p.P958S on NM_020789.4) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV57422523; called by muse, varscan2
- KCNJ4 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs753595753, COSV57856295; called by muse, mutect2, varscan2
- MED1 | c.2408T>C p.I803T | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); catalogued as rs763945027; called by muse, mutect2, varscan2
- NLRC5 | c.3107C>T p.S1036F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs781610538; called by muse, varscan2
- NLRP3 | c.730G>C p.G244R | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100276546; called by muse, mutect2, varscan2
- OBSCN | c.18574C>T p.R6192W | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1042965818, COSV52783232; called by muse, varscan2
- OR5H1 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 178/593 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs1215424539; called by muse, mutect2, varscan2
- PCDH11X | c.3166C>A p.H1056N | Missense Mutation (SNP) | VAF 206/931 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV53510400; called by muse, mutect2, varscan2
- SFRP4 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.017); catalogued as COSV71412417; called by muse, mutect2
- SOHLH1 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs138188914; called by muse, mutect2, varscan2
- ZFHX4 | c.9217G>A p.V3073M | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51464616; called by muse, mutect2, varscan2
- BHLHE41 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.302); called by muse, mutect2
- EMC9 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 16/361 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GK2 | c.311C>A p.T104K | Missense Mutation (SNP) | VAF 106/668 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNH3 | c.3094C>T p.P1032S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by muse, mutect2
- LRRIQ3 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 45/598 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2
- LUZP2 | c.252-1G>A p.X84_splice | Splice Site (SNP) | VAF 47/497 reads (9%) | called by muse, mutect2
- MAGI1 | c.4085G>C p.R1362T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, varscan2
- MMD2 | c.239T>A p.F80Y | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSME4 | c.4345G>C p.E1449Q | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- SHOX2 | c.631G>T p.A211S (on ENST00000441443 / NM_006884.3; = p.A235S on NM_003030.4) | Missense Mutation (SNP) | VAF 48/526 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.082); called by muse, mutect2
- SLPI | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- TGM4 | c.672A>C p.K224N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- VPS13C | c.4680C>A p.F1560L (on ENST00000644861 / NM_020821.3; = p.F1517L on NM_017684.5) | Missense Mutation (SNP) | VAF 80/783 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- VWA7 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); called by muse, mutect2
- CHIT1 | c.168C>T p.Y56= | Silent (SNP) | VAF 121/887 reads (14%) | catalogued as rs149551689; called by muse, mutect2, varscan2
- FGD1 | c.192G>A p.S64= | Silent (SNP) | VAF 55/225 reads (24%) | catalogued as rs746279011; called by muse, mutect2, varscan2
- KRTAP2-2 | c.192C>T p.C64= | Silent (SNP) | VAF 3/126 reads (2%) | called by muse, mutect2
- PIK3R6 | c.237T>A p.T79= | Silent (SNP) | VAF 57/218 reads (26%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.1371C>T p.G457= | Silent (SNP) | VAF 27/340 reads (8%) | called by muse, mutect2
- SPG21 | c.630A>G p.E210= | Silent (SNP) | VAF 72/605 reads (12%) | called by muse, mutect2, varscan2
- SULF1 | c.1905G>T p.S635= | Silent (SNP) | VAF 44/624 reads (7%) | called by muse, mutect2
- UHRF1 | c.1548C>T p.I516= (on ENST00000612630 / NM_001290050.1; = p.I529= on NM_013282.4) | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.780G>T | RNA (SNP) | VAF 76/359 reads (21%) | catalogued as rs763394829; called by muse, mutect2, varscan2
- SPATA31C1 | n.3385A>T | RNA (SNP) | VAF 20/124 reads (16%) | called by mutect2, varscan2
- SPATA31C2 | n.3268A>T | RNA (SNP) | VAF 84/1750 reads (5%) | catalogued as rs752680637; called by muse, mutect2
- ST7 | c.151+2874C>T | Intron (SNP) | VAF 78/686 reads (11%) | called by muse, mutect2, varscan2
